FM case AD11271 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified urinary organs.
https://portal.gdc.cancer.gov/cases/38440fd0-6ae7-440f-835f-85adebb3fa6e

Female, 61.0 years: diagnosis not reported by GDC of the urinary system; metastasis biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
